Somatic mutation profile of tumor specimen TCGA-AA-3680-01A (aliquot TCGA-AA-3680-01A-01W-0900-09) from TCGA case TCGA-AA-3680, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IV; Age at diagnosis: 67.5 years (24,655 days).
Specimen TCGA-AA-3680-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8e9430a-5527-45ca-ba97-9fcda62f9578.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3680-10A (Blood Derived Normal), aliquot TCGA-AA-3680-10A-01W-0900-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c30e20b0-9373-4623-9564-571f772e95e3

The open-access MAF lists 119 somatic variants for this specimen: 95 protein-altering or splice-affecting, 21 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 21, Frame Shift Del 9, Nonsense Mutation 8, Splice Site 2, RNA 2, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.2893C>T p.R965* | Nonsense Mutation (SNP) | VAF 39/99 reads (39%) | catalogued as rs397515401, CM122406, COSV60107754, COSV60115393; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 57/97 reads (59%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AASDHPPT | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 57/97 reads (59%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.85); catalogued as rs1286428407, COSV53789451; called by muse, mutect2, varscan2
- ABCA4 | c.6319C>T p.R2107C | Missense Mutation (SNP) | VAF 56/116 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs2297669, CM015858; called by muse, mutect2, varscan2
- ABRA | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.186); catalogued as rs780637593, COSV61731924; called by muse, mutect2, varscan2
- ADAR | c.2300G>T p.R767L | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52715179, COSV52717301; called by muse, mutect2, varscan2
- AMER1 | c.1489C>T p.R497* | Nonsense Mutation (SNP) | VAF 68/186 reads (37%) | catalogued as COSV57655167; called by muse, mutect2, varscan2
- APC | c.3488del p.S1163Tfs*2 | Frame Shift Del (DEL) | VAF 75/222 reads (34%) | catalogued as COSV57355120; called by mutect2, pindel, varscan2
- ATP13A4 | c.3039C>A p.S1013R | Missense Mutation (SNP) | VAF 115/369 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV61321657; called by muse, mutect2, varscan2
- BMP15 | c.997A>G p.N333D | Missense Mutation (SNP) | VAF 81/252 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV53140910; called by muse, mutect2, varscan2
- CACNA1S | c.2275C>T p.R759C | Missense Mutation (SNP) | VAF 69/158 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs777247285, COSV62941024; called by muse, mutect2, varscan2
- CBLN4 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.626); catalogued as COSV99290427; called by muse, mutect2
- CCDC110 | c.2248G>A p.V750I | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.654); catalogued as rs767005070, COSV56872076; called by muse, mutect2, varscan2
- CCSER2 | c.2345C>T p.S782F | Missense Mutation (SNP) | VAF 92/236 reads (39%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); catalogued as COSV56507500, COSV56510013; called by muse, mutect2, varscan2
- CD14 | c.1064C>T p.S355L | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as rs748409113, COSV57370960; called by muse, mutect2, varscan2
- COL19A1 | c.813G>A p.M271I | Missense Mutation (SNP) | VAF 109/290 reads (38%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV59577276; called by muse, mutect2, varscan2
- CTNNBL1 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.515); catalogued as rs1209318822, COSV63743906; called by muse, mutect2, varscan2
- DNAH5 | c.13774C>T p.R4592* | Nonsense Mutation (SNP) | VAF 99/198 reads (50%) | catalogued as rs758112779, COSV54210253, COSV54253592, COSV99455552; called by muse, mutect2, varscan2
- DNAI4 | c.844G>A p.G282S | Missense Mutation (SNP) | VAF 104/311 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as rs1371567301, COSV64019089; called by muse, mutect2, varscan2
- DNPEP | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.703); catalogued as COSV56111230; called by muse, mutect2, varscan2
- DYSF | c.1828G>A p.A610T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as rs886043941, COSV50325367; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPG5 | c.5592C>G p.S1864R | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV56351687; called by muse, mutect2
- EPHB1 | c.2717C>G p.S906C | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.666); catalogued as COSV67664247; called by muse, mutect2, varscan2
- FRYL | c.4436-2A>G p.X1479_splice | Splice Site (SNP) | VAF 26/63 reads (41%) | catalogued as COSV99976316; called by muse, mutect2, varscan2
- GFOD1 | c.817C>G p.P273A | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV64954674, COSV64954903; called by muse, mutect2, varscan2
- GLIS3 | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs770212930, COSV60927654; called by muse, mutect2, varscan2
- GPR12 | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs753635977, COSV67344437; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1211A>T p.Y404F | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as COSV56088053; called by muse, mutect2, varscan2
- HS3ST5 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 123/292 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs746548752, COSV57144351; called by muse, mutect2, varscan2
- IGDCC3 | c.1372G>A p.V458I | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1454719478, COSV60078319; called by muse, mutect2, varscan2
- IRX6 | c.1311C>A p.C437* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as COSV51861002; called by muse, mutect2, varscan2
- KANSL3 | c.1214G>T p.G405V | Missense Mutation (SNP) | VAF 132/377 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62618819; called by muse, mutect2, varscan2
- KATNAL2 | c.1381G>T p.E461* (on ENST00000356157 / NM_001353899.1; = p.E389* on NM_031303.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 54/125 reads (43%) | catalogued as COSV55301804; called by muse, mutect2, varscan2
- KCNB2 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 203/588 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV73049920, COSV73053662; called by muse, mutect2, varscan2
- KIF13A | c.833C>T p.S278L | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52449761; called by muse, mutect2, varscan2
- KPNB1 | c.1816G>A p.V606M | Missense Mutation (SNP) | VAF 67/160 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.228); catalogued as COSV51598057; called by muse, mutect2, varscan2
- KRTAP27-1 | c.347G>T p.C116F | Missense Mutation (SNP) | VAF 128/294 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.758); catalogued as COSV67001341, COSV67001788; called by muse, mutect2, varscan2
- LRRK2 | c.6448G>A p.V2150I | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs755564073, COSV54158627; called by muse, mutect2, varscan2
- MTCL1 | c.1337G>A p.R446H (on ENST00000306329 / NM_001378206.1; = p.R86H on NM_015210.4) | Missense Mutation (SNP) | VAF 71/207 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371187347; called by muse, mutect2, varscan2
- MTMR6 | c.626G>T p.G209V | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67808752; called by muse, mutect2, varscan2
- MYO18A | c.4456C>T p.R1486W | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1171159923, COSV62868942; called by muse, mutect2, varscan2
- NRBP1 | c.89T>C p.V30A | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs1299943305, COSV51994791; called by muse, mutect2, varscan2
- OR10W1 | c.295G>A p.G99S | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.175); catalogued as COSV101223632; called by muse, mutect2
- OR1L1 | c.209G>A p.R70Q (on ENST00000373686; = p.R20Q on NM_001005236.3) | Missense Mutation (SNP) | VAF 173/416 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs146350628; called by muse, mutect2, varscan2
- OR2G6 | c.397A>G p.I133V | Missense Mutation (SNP) | VAF 62/238 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1441129632, COSV58574954; called by muse, mutect2, varscan2
- OR52E8 | c.336C>A p.F112L | Missense Mutation (SNP) | VAF 220/550 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs767765341, COSV66204650, COSV66210663; called by muse, mutect2, varscan2
- OR52J3 | c.370C>A p.R124S | Missense Mutation (SNP) | VAF 76/206 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV66747279; called by muse, mutect2
- OSBPL6 | c.1655G>A p.R552Q | Missense Mutation (SNP) | VAF 63/153 reads (41%) | SIFT tolerated (0.65); PolyPhen benign (0.103); catalogued as rs377158599; called by muse, mutect2, varscan2
- OTUD6A | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57973757; called by muse, mutect2, varscan2
- OVCH1 | c.910C>A p.P304T | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.039); catalogued as rs758473355, COSV58964822; called by muse, mutect2, varscan2
- PALLD | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 71/187 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1458454631, COSV54976460; called by muse, mutect2, varscan2
- PCDHB14 | c.1900G>A p.D634N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs782306872, COSV53389172; called by muse, mutect2, varscan2
- PCDHB6 | c.1411G>A p.V471I | Missense Mutation (SNP) | VAF 92/257 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.058); catalogued as COSV50699885; called by muse, mutect2, varscan2
- PER3 | c.2395G>A p.V799I | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as rs1204640701, COSV62704202, COSV62704422; called by muse, mutect2, varscan2
- PGBD5 | c.635G>A p.R212Q (on ENST00000525115; = p.R281Q on NM_001258311.2) | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs375905173; called by muse, mutect2, varscan2
- PKHD1 | c.5687C>T p.T1896M | Missense Mutation (SNP) | VAF 63/160 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs140996978; called by muse, mutect2, varscan2
- PLXNA4 | c.4904G>A p.R1635H | Missense Mutation (SNP) | VAF 151/587 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); catalogued as rs754615235, COSV58137527; called by muse, mutect2, varscan2
- PRPF8 | c.4241G>A p.R1414H | Missense Mutation (SNP) | VAF 75/179 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV59264645; called by muse, mutect2, varscan2
- PRPF8 | c.384del p.F128Lfs*23 | Frame Shift Del (DEL) | VAF 22/69 reads (32%) | catalogued as COSV100516990, COSV59264658; called by mutect2, pindel, varscan2
- RANBP2 | c.1542C>A p.C514* | Nonsense Mutation (SNP) | VAF 63/335 reads (19%) | catalogued as COSV51703147; called by muse, mutect2, varscan2
- RELN | c.3526T>C p.F1176L | Missense Mutation (SNP) | VAF 59/130 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV59012429; called by muse, mutect2, varscan2
- RIMS2 | c.2470C>T p.R824* (on ENST00000666250 / NM_001348490.2; = p.R632* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 105/230 reads (46%) | catalogued as rs561377229, COSV51662074, COSV51700955; called by muse, mutect2, varscan2
- RNF169 | c.1238A>G p.N413S | Missense Mutation (SNP) | VAF 44/318 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs779305012, COSV55133506; called by muse, mutect2
- RNF20 | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 119/317 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.072); catalogued as rs368721473, COSV101206512; called by muse, mutect2, varscan2
- RTL9 | c.3362C>T p.S1121L | Missense Mutation (SNP) | VAF 220/572 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as rs771130284, COSV71825811; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SERPINB11 | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0.397); catalogued as rs766193301, COSV66957238; called by muse, mutect2, varscan2
- SETD2 | c.6863C>T p.P2288L | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.63); catalogued as COSV57441773; called by muse, mutect2, varscan2
- SLC18A3 | c.1535G>A p.R512H | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV60327487; called by muse, mutect2, varscan2
- SLC25A14 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as COSV54418841; called by muse, mutect2, varscan2
- SLITRK1 | c.1741C>A p.L581M | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.358); catalogued as COSV65674069; called by muse, mutect2
- SNAP47 | c.796A>G p.T266A | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT tolerated (0.99); PolyPhen benign (0.015); catalogued as COSV59918550; called by muse, mutect2, varscan2
- TBCEL | c.987G>T p.K329N | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV52460660; called by muse, mutect2, varscan2
- THBS2 | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs766329088, COSV64676973; called by muse, mutect2
- TM9SF4 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750795353, COSV54108230; called by muse, mutect2, varscan2
- TMEM147 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs905580579, COSV52867332; called by muse, mutect2, varscan2
- TNPO2 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV63508234; called by muse, mutect2, varscan2
- TSHZ2 | c.334G>A p.V112I | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs773829843, COSV61589587; called by muse, mutect2
- TUBB6 | c.730G>T p.G244C | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV52315449; called by muse, mutect2, varscan2
- UNC79 | c.4375G>A p.E1459K (on ENST00000393151 / NM_001346218.2; = p.E1282K on NM_020818.5) | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.848); catalogued as rs759942741, COSV56394736; called by muse, mutect2, varscan2
- VCAN | c.10063+1G>A p.X3355_splice | Splice Site (SNP) | VAF 41/172 reads (24%) | catalogued as COSV54107235; called by muse, mutect2, varscan2
- WNT3A | c.83T>C p.V28A | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.075); catalogued as COSV52731907; called by muse, mutect2, varscan2
- YARS2 | c.906G>T p.L302F | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.075); catalogued as COSV61402109; called by muse, mutect2, varscan2
- ZBTB7B | c.172T>C p.Y58H (on ENST00000292176; = p.Y92H on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52693401; called by muse, mutect2, varscan2
- ZIC4 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1332082789, COSV67172905; called by muse, mutect2
- ZNF213 | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.1); PolyPhen benign (0.215); catalogued as rs371164415; called by muse, mutect2, varscan2
- ZNF256 | c.856C>T p.R286* | Nonsense Mutation (SNP) | VAF 68/345 reads (20%) | catalogued as rs748369479, COSV56598104; called by muse, mutect2, varscan2
- ZNF284 | c.1597C>T p.H533Y | Missense Mutation (SNP) | VAF 80/178 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs868001586, COSV101399025, COSV69691280; called by muse, mutect2, varscan2
- ABCB4 | c.753del p.A252Qfs*15 | Frame Shift Del (DEL) | VAF 92/222 reads (41%) | called by mutect2, pindel, varscan2
- AOC2 | c.926_944del p.Q309Pfs*27 | Frame Shift Del (DEL) | VAF 68/188 reads (36%) | called by mutect2, pindel, varscan2
- APC | c.4720del p.I1574Yfs*2 | Frame Shift Del (DEL) | VAF 110/358 reads (31%) | called by mutect2, pindel, varscan2
- BIRC6 | c.10511_10514del p.S3504Mfs*5 | Frame Shift Del (DEL) | VAF 22/148 reads (15%) | called by mutect2, pindel, varscan2
- LAMA2 | c.6840dup p.V2281Cfs*12 | Frame Shift Ins (INS) | VAF 114/379 reads (30%) | called by mutect2, pindel, varscan2
- ORC1 | c.270_279del p.R91Kfs*42 | Frame Shift Del (DEL) | VAF 52/181 reads (29%) | called by mutect2, pindel, varscan2
- SLFN5 | c.481_512delinsT p.S161* | Frame Shift Del (DEL) | VAF 61/186 reads (33%) | called by pindel, varscan2*
- TNFSF13B | c.211_256del p.A71Tfs*27 | Frame Shift Del (DEL) | VAF 15/96 reads (16%) | called by mutect2, pindel
- ALOX15 | c.1935C>T p.D645= | Silent (SNP) | VAF 41/131 reads (31%) | catalogued as COSV53398663; called by muse, mutect2, varscan2
- CR2 | c.1044G>A p.A348= | Silent (SNP) | VAF 48/127 reads (38%) | catalogued as rs144982406, COSV100889635; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCLK3 | c.1620C>T p.G540= | Silent (SNP) | VAF 211/372 reads (57%) | catalogued as rs771625779, COSV69363723; called by muse, mutect2, varscan2
- DPH7 | c.837G>A p.T279= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs751150227, COSV53022636; called by muse, mutect2, varscan2
- GABRR1 | c.561C>A p.L187= | Silent (SNP) | VAF 98/255 reads (38%) | catalogued as COSV65619773; called by muse, mutect2, varscan2
- LAMA4 | c.945C>T p.N315= (on ENST00000230538 / NM_001105206.3; = p.N308= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/103 reads (34%) | catalogued as rs782772720, COSV57899721; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRRC4B | c.1098C>T p.I366= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as rs550149281, COSV100975991, COSV65349627; called by muse, mutect2, varscan2
- MCTP1 | c.1473C>T p.S491= | Silent (SNP) | VAF 36/124 reads (29%) | catalogued as rs748000446, COSV56522053; called by muse, mutect2, varscan2
- MKS1 | c.528C>T p.I176= | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as COSV58304782; called by muse, mutect2, varscan2
- MROH2B | c.324C>T p.F108= | Silent (SNP) | VAF 74/167 reads (44%) | catalogued as rs371986783; called by muse, mutect2, varscan2
- NSD2 | c.1740G>A p.S580= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as rs772571701, COSV56387751; called by muse, mutect2, varscan2
- OR2T33 | c.159C>T p.L53= | Silent (SNP) | VAF 49/248 reads (20%) | catalogued as COSV58818126; called by muse, mutect2, varscan2
- PML | c.1230C>T p.P410= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV51448878; called by muse, mutect2, varscan2
- PSMD10 | c.130T>C p.L44= | Silent (SNP) | VAF 56/430 reads (13%) | catalogued as COSV54264343; called by muse, mutect2, varscan2
- PTCHD4 | c.1461C>T p.D487= | Silent (SNP) | VAF 37/83 reads (45%) | catalogued as rs528743841, COSV59788674; called by muse, mutect2, varscan2
- RAB40AL | c.807C>T p.N269= | Silent (SNP) | VAF 70/174 reads (40%) | catalogued as COSV54434899; called by muse, mutect2, varscan2
- RADX | c.570G>A p.A190= | Silent (SNP) | VAF 89/246 reads (36%) | catalogued as COSV65319121; called by muse, mutect2, varscan2
- SARDH | c.576G>A p.P192= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs1452412722, COSV53834335; called by muse, mutect2, varscan2
- SEMA3F | c.2013C>T p.S671= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as rs373344301; called by muse, mutect2, varscan2
- VSIG10 | c.183G>A p.S61= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs117781232; called by muse, mutect2
- ZNF569 | c.1902C>T p.F634= | Silent (SNP) | VAF 167/345 reads (48%) | catalogued as rs762580025, COSV57593729; called by muse, mutect2, varscan2
- KNOP1P1 | n.398G>T | RNA (SNP) | VAF 44/329 reads (13%) | called by muse, mutect2, varscan2
- PCID2 | c.266+72G>A | Intron (SNP) | VAF 44/153 reads (29%) | catalogued as COSV55813720; called by muse, mutect2, varscan2
- SSX6P | n.138G>C | RNA (SNP) | VAF 147/346 reads (42%) | catalogued as rs782246343; called by muse, mutect2, varscan2
